Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A8YE, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A8YE-06A (Metastatic).

DERMATOPATHOLOGY

Case Number :

12003

Melanoma NOS 872013
Site Lymph node, axilla
C773
12/4/13/14

Diagnosis:

A: Lymph nodes, left axilla, level 3, removal

-No evidence of melanoma in 9 lymph nodes (0/9)

B: Lymph nodes, left axilla, levels 1 & 2, removal

-Metastatic melanoma involving 1 out of 21 lymph nodes, with the largest diameter measuring 4 cm and no evidence of capsular involvement or extracapsular extension (1/21)

-10% of the tumor is necrotic

Clinical History:

-year-old male with left axillary lymph node dissection

Gross Description:

A: The specimen was received labeled with the patient's name and measured 6 x 2 x 0.5 cm. The tissue is entirely submitted as A1-A5,

B: The specimen was received labeled with the patient's name and measured 8.5 x 8 x 3.5 cm. There is a 4 x 4 x 3 cm mass; a fresh portion is taken by tissue procurement. The fibrofatty specimen is serially sectioned and then placed in . Lymph node candidates are identified and submitted as B1-B11.

Tissue remains in formalin.

Source: NCI Genomic Data Commons file b95e9e4a-635f-479c-916d-c85a484e0dde (TCGA-FR-A8YE.FDE8D45A-BFC5-4A27-A0E3-F683FA318EFF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).